Gene-level copy-number profile of tumor specimen TCGA-HM-A3JJ-01A from TCGA case TCGA-HM-A3JJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 40.3 years (14,736 days).
Specimen TCGA-HM-A3JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6d671137-cc39-4651-bfcd-a6e36466a963.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HM-A3JJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/300f3e83-6e16-4090-acd4-1df702026f7c

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,186; copy number 4: 22,976; copy number 6: 25,681; copy number 7: 3,329; copy number 8: 1,583; copy number 9: 1,670; copy number 10: 30; copy number 11: 464; copy number 12: 90; copy number 13: 2,612; copy number 14: 5; copy number 15: 10; copy number 16: 5; copy number 20: 89; copy number 24: 30; copy number 25: 3; copy number 28: 32; copy number 38: 4; copy number 49: 3; copy number 64: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HM-A3JJ-01A-21D-A21P-01): tumor purity 0.42, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 435 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,858,659–180,037,053, 170 genes, copy number 14–38 (broad region; genes not listed).
- chr5:5,688,805–19,234,487, 236 genes, copy number 13 (broad region; genes not listed).
- chr7:53,187,388–53,366,209, 3 genes, copy number 25: HAUS6P1, RNF138P2, RNU1-14P.
- chr11:100,666,459–102,378,670, 26 genes, copy number 16–64: PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
